Somatic mutation profile of tumor specimen TARGET-30-PAPBGH-01A (aliquot TARGET-30-PAPBGH-01A-01W) from TARGET case TARGET-30-PAPBGH, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.9 years (1,074 days).
Specimen TARGET-30-PAPBGH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d603df0d-db70-4727-9a4f-63c4c40d5d13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPBGH-10A (Blood Derived Normal), aliquot TARGET-30-PAPBGH-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1553d3f3-927b-4522-9801-10c1a09384e0

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 19, Silent 6, In Frame Del 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM234B | c.1547C>A p.P516Q | Missense Mutation (SNP) | VAF 173/599 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.104); catalogued as COSV52194973; called by muse, mutect2, varscan2
- FBN2 | c.5459C>A p.A1820E | Missense Mutation (SNP) | VAF 141/358 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.029); catalogued as COSV52517909, COSV52543406; called by muse, mutect2, varscan2
- ILDR2 | c.692G>T p.C231F | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1157475111, COSV54831519; called by muse, mutect2, varscan2
- KBTBD4 | c.880A>T p.I294F | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.802); catalogued as COSV58596870; called by muse, mutect2, varscan2
- KLF4 | c.1237C>T p.L413F | Missense Mutation (SNP) | VAF 77/470 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65929021; called by muse, mutect2, varscan2
- NLRP7 | c.2376G>T p.K792N (on ENST00000340844 / NM_206828.3; = p.K764N on NM_139176.3) | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.127); catalogued as COSV60175645; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1409A>G p.D470G (on ENST00000352766; = p.D391G on NM_181334.5) | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); catalogued as rs1289605882, COSV104396481, COSV61234092; called by muse, mutect2, varscan2
- PYHIN1 | c.132C>A p.D44E | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV63722701; called by muse, mutect2, varscan2
- SAGE1 | c.506C>A p.P169H | Missense Mutation (SNP) | VAF 85/220 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV61014129; called by muse, mutect2, varscan2
- SULT1A2 | c.543G>T p.E181D | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as COSV57681952; called by muse, mutect2, varscan2
- TAGAP | c.2024C>A p.A675D | Missense Mutation (SNP) | VAF 59/209 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.467); catalogued as COSV57852160; called by muse, mutect2, varscan2
- TAT | c.1096G>A p.V366I | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0.005); catalogued as COSV63532975; called by muse, mutect2, varscan2
- UBN2 | c.1279G>C p.E427Q | Missense Mutation (SNP) | VAF 9/278 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV56035115, COSV99943985; called by muse, mutect2
- ZNF292 | c.6917C>A p.A2306E | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.895); catalogued as COSV60540344; called by muse, mutect2, varscan2
- ZNF595 | c.562A>T p.T188S | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs781994114, COSV59550611; called by muse, mutect2, varscan2
- DCUN1D1 | c.604-5_604-2del p.X202_splice | Splice Site (DEL) | VAF 5/65 reads (8%) | called by mutect2, pindel
- GABRG1 | c.683C>A p.A228D | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- GABRG1 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- KRT6C | c.972C>A p.N324K | Missense Mutation (SNP) | VAF 38/716 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MSANTD4 | c.212G>T p.R71I | Missense Mutation (SNP) | VAF 126/1863 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PSD4 | c.1065del p.R355Sfs*16 | Frame Shift Del (DEL) | VAF 72/835 reads (9%) | called by mutect2, pindel
- TMEM131 | c.4198_4200del p.K1400del | In Frame Del (DEL) | VAF 53/183 reads (29%) | called by mutect2, pindel, varscan2
- CNTN5 | c.1293A>C p.S431= | Silent (SNP) | VAF 66/165 reads (40%) | catalogued as COSV54316886; called by muse, mutect2, varscan2
- DNAH3 | c.12138G>T p.L4046= | Silent (SNP) | VAF 103/261 reads (39%) | catalogued as COSV54526161; called by muse, mutect2, varscan2
- FAM71B | c.1071C>A p.S357= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV57229374; called by muse, mutect2, varscan2
- LRRC37A3 | c.3762C>T p.G1254= | Silent (SNP) | VAF 39/170 reads (23%) | catalogued as rs373962772; called by muse, mutect2, varscan2
- OR5D16 | c.324C>A p.T108= | Silent (SNP) | VAF 30/873 reads (3%) | called by muse, mutect2
- TCF20 | c.738C>A p.S246= | Silent (SNP) | VAF 216/475 reads (45%) | catalogued as rs1205425807, COSV59492041; called by muse, mutect2, varscan2
